Gene-level copy-number profile of tumor specimen HCM-CSHL-0853-C56-07B from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-07B: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3bdaf84d-8361-4799-953d-d90b0fd11234.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0853-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/d8f4a479-55c2-40fa-bd66-8e3b8c52463d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,958; copy number 2: 30,975; copy number 3: 4,831; copy number 4: 778; copy number 5: 122; copy number 6: 580; copy number 7: 129; copy number 8: 12.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 843 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:75,921,114–76,072,678, 1 gene, copy number 5 (within-gene range 3–5): IMPG1.
- chr6:76,092,834–76,092,940, 1 gene, copy number 5: RNU6-248P.
- chr8:91,909,738–145,066,685, 841 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
